Surgical pathology report (de-identified scan), TCGA case TCGA-OR-A5K9, project TCGA-ACC (Adrenocortical Carcinoma), tissue source site University of Michigan, specimen TCGA-OR-A5K9-01A (Primary Tumor).

PREVIOUS DIAGNOSIS INQUIRY

PAT TYPE:

PAGE #: 1
SEX: F
ADM DATE:

OPER DATE:

PROCEDURE: SPHS

Year-old with history of adrenal mass and Cushing's syndrome per CT. No mets. Operative Procedure: Right adrenalectomy, right nephrectomy, wedge resection of liver.

PROCEDURE: SPGD

1. "R. radical adrenalectomy." Received fresh is a 253 gram trimmed portion of ovoid possible adrenal tissue, 9.3 x 8.2 x 6.7 cm. The cut surface reveals a 9.8 x 7.3 x 6.0 cm hemorrhagic possibly necrotic tan tumor that abuts the margin. A scant amount of bright orange-yellow tissue is identified measuring 3.7 x 1.3 x 0.8 cm. Attached to the periadrenal adipose is a 4.3 x 2.2 x 0.3 cm possible portion of liver. The cut surface is red-brown. Also attached to the periadrenal adipose is a 193 gram kidney, 11 x 6 x 4.2 cm. The cut surface of the kidney is a tan-brown with a well-defined corticomedullary junction. No lesions are noted. The adrenal gland is somewhat embedded within the kidney cortex. No other lesions are noted.

- 1A-I. Adrenal mass.
- 1J. Adrenal mass to possible liver.
- 1K. Kidney margins.
- 1L. Adrenal gland to kidney.
- 1M. Normal kidney.

PROCEDURE: SPDY

1. Right adrenal and kidney, excision: Adrenal cortical carcinoma (9.8 cm), high-grade, adherent to, but not directly invading, the kidney and liver. Margins negative. Histologically unremarkable kidney. Case reviewed by

the signing staff pathologist, have personally examined and interpreted the slides from this case.

** END OF PREVIOUS DIAGNOSIS INQUIRY **

ICD-O-3

Carcinoma, adrenal
Cortical 8870/3
Site: Adrenal Gland
Cortex C74.0
JND 1/28/13

Source: NCI Genomic Data Commons file 5ce389c3-ed89-4dad-9b7d-24ab160422c0 (TCGA-OR-A5K9.EAC92541-2274-4FB8-B56B-657413EDF0F9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).